Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A3HR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A3HR-01A (Primary Tumor).

Procurement Date: Laterality:

Path Report: CERVIX TISSUE CHECKLIST

Specimen type: Hysterectomy, bilateral salpingo-oophorectomy

Tumor site: Cervix

Tumor size: 1 x 0.8 x 0.5 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Lesion less than 4.0 cm

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

100-0-3

carcinoma, squamous cell 8070/3

Site: cervix, NOS C53.9

fw 12/1/11

Gross Description:

Microscopic Description:

Diagnosis Details:

Source: NCI Genomic Data Commons file 56aafa75-d636-4663-a289-d5763b078cd6 (TCGA-EA-A3HR.BE99BE0C-3FB8-4AE6-B66D-977B858D880E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).